Somatic mutation profile of tumor specimen CPT008929 (aliquot CPT008929-0002) from CPTAC case 01BR023, project CPTAC-2 (Breast). Tissue or organ of origin: Breast, NOS.
Specimen CPT008929: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5397e9c7-0ecb-48bc-b48a-41bdda88baf2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CPT008543 (Blood Derived Normal), aliquot CPT008543-0001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5fb88a3e-7295-4706-a9d7-3f5f2f19f369

The open-access MAF lists 22 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 5, Intron 4, In Frame Del 2, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARAP3 | c.1504C>T p.R502W | Missense Mutation (SNP) | VAF 179/612 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs976476927, COSV53348668; called by muse, mutect2, varscan2
- FLG | c.6859G>A p.E2287K | Missense Mutation (SNP) | VAF 88/272 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.018); catalogued as rs199574917; called by muse, mutect2, varscan2
- MAPK13 | c.129C>G p.I43M | Missense Mutation (SNP) | VAF 109/283 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.079); catalogued as COSV52984143; called by muse, mutect2, varscan2
- PACSIN2 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as rs1489342287; called by muse, mutect2, varscan2
- TRPC1 | c.2221C>T p.R741C (on ENST00000476941 / NM_001251845.2; = p.R707C on NM_003304.4) | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs538677775, COSV56425259; called by muse, mutect2, varscan2
- TTN | c.67850T>C p.I22617T (on ENST00000591111; = p.I15193T on NM_003319.4) | Missense Mutation (SNP) | VAF 15/30 reads (50%) | PolyPhen benign (0.202); catalogued as rs773657520; called by muse, mutect2, varscan2
- UGDH | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 30/504 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as rs368044471, COSV57097253; called by muse, mutect2
- BCHE | c.1152_1154del p.F386del | In Frame Del (DEL) | VAF 17/51 reads (33%) | called by mutect2, pindel, varscan2
- UBE2B | c.253_264del p.G85_C88del | In Frame Del (DEL) | VAF 22/171 reads (13%) | called by mutect2, pindel, varscan2
- WDR7 | c.3557C>A p.P1186H | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZDHHC4 | c.68T>A p.V23D | Missense Mutation (SNP) | VAF 62/235 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- AK5 | c.39G>A p.R13= | Silent (SNP) | VAF 41/173 reads (24%) | catalogued as rs1296451062; called by muse, mutect2, varscan2
- BBS7 | c.483C>T p.I161= | Silent (SNP) | VAF 93/242 reads (38%) | called by muse, mutect2, varscan2
- DNHD1 | c.5169C>T p.S1723= | Silent (SNP) | VAF 53/237 reads (22%) | called by muse, mutect2, varscan2
- LRRC4B | c.1539G>A p.P513= | Silent (SNP) | VAF 78/252 reads (31%) | called by mutect2, varscan2
- SLC66A1 | c.429G>A p.A143= | Silent (SNP) | VAF 47/100 reads (47%) | catalogued as rs370387864; called by muse, mutect2, varscan2
- HROB | c.-43G>A | 5'UTR (SNP) | VAF 79/379 reads (21%) | called by muse, mutect2, varscan2
- LILRB5 | c.34+15G>A | Intron (SNP) | VAF 98/249 reads (39%) | catalogued as rs754685460; called by muse, varscan2
- MAPT | c.1732+2383C>A | Intron (SNP) | VAF 26/138 reads (19%) | catalogued as rs867623167; called by muse, mutect2, varscan2
- MFSD9 | c.253+186G>A | Intron (SNP) | VAF 29/131 reads (22%) | catalogued as rs549416351; called by muse, mutect2, varscan2
- OR7E14P | n.699C>A | RNA (SNP) | VAF 39/166 reads (23%) | called by muse, mutect2, varscan2
- PPP2R5D | c.1482-18C>A | Intron (SNP) | VAF 123/333 reads (37%) | called by muse, mutect2, varscan2
